TCGA case TCGA-ZN-A9VW — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Brigham and Women's Hospital Division of Thoracic Surgery. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/54d21956-25e4-42df-adbe-6907721fc4b5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Dead; Days to death: 84 days.

Diagnoses (2)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 61.8 years (22,588 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Thorax, NOS. Age at diagnosis: 61.8 years (22,558 days); Days to diagnosis: -30 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 0 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (3 entries)
- Day -30 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: -30 days.
- Days to follow up: 84 days; Disease response: With Tumor.
- Imaging anatomic site: Pleura; Imaging suv max: 8.6; Timepoint: Prior to Treatment.

Molecular and laboratory tests
- Serum Mesothelin 2.7 nmol/L [Blood test normal range lower: 0; Blood test normal range upper: 1.5].
- Creatinine 0.86 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.2].

Exposures
- Occupation type: Armed Forces Occupations, Other Ranks.
- Exposure type: Asbestos; Exposure source: Occupational.

Family history
- Relative with cancer history: yes; Relationship type: Grandparent.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZN-A9VW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-ZN-A9VW-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-ZN-A9VW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: military, trucking, environmental exposures.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma; Serum mesothelin prior treatment: 2.7.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 84 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 84 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), time not recorded.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZN-A9VW-01A-11D-A39Q-01): tumor purity 0.65, ploidy 1.96, whole-genome doublings 0.
